Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EO, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EO-01A (Primary Tumor).

[page 1 of 2]
ICD O 3

Date of surgery :

Melanoma epithelioid +
spindle cell mixed 8720/3

Left eye enucleation

Site ^{C6.4} Ciliary body C6.4
^{path} Uveal tract C6.4

9/23/10/14

Macroscopy

The eye ball measures 25 mm and presents a posterior segment of optic nerves measuring 2 mm. At the section, the tumor measures 19 mm main line. Samples have been frozen for genetic studies then the piece has been fixed and included entirely.

Microcopy

See path discrepancy form for epithelioid and
spindle cell ratio.

The tumor observed macroscopically corresponds to an uveal melanoma, mainly composed of epithelioid cells (80%). The tumor cells are large in size and present a vesicular nucleus with mild atypia. The cells are often loaded with melanin. The mitotic index is low (4 mitoses per 10 HPF).

The tumor is developed on the temporal side of the eye. At the anterior part, the tumor infiltrates the lateral part of the iris and the ciliary body. At the posterior part, the tumor is close to the optic foramen. However, the optic nerve on its entire course and its cut end are free of tumor, as well as the meningeal sheets. The sclera is also free and there is no tumor endovascular embolism.

Conclusion

Uveal melanoma of the left eye.

Epithelioid cells predominant.

Tumor size: 19 mm.

Low mitotic index.

Invasion of the periphery of the iris and of the ciliary body.

No scleral or extrascleral involvement

The optic nerve on its entire course, its cut end and the meningeal sheets are free.

HPV Discrepancy		
Case is Circled		

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

VA.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	80% epithelioid cells 20% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d1b33537-ee1c-40be-93a9-d9f442e52d42 (TCGA-V4-A9EO.04475A61-A4E9-482C-B0B8-48B852636AE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).